Surgical pathology report (de-identified scan), TCGA case TCGA-HC-7080, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-HC-7080-01A (Primary Tumor).

[page 1 of 2]
Collection Date: [REDACTED]
Hospital of Origin: [REDACTED]
Copy to: [REDACTED]

TCGA-HC-7080

QC Pathologist:

FINAL PATHOLOGIC DIAGNOSIS:

A. Prostate, bilateral seminal vesicles, vas deferens, proctectomy:

Tumor Characteristics:

1. Histologic type: Adenocarcinoma.
2. Prostate size: 39 gm, 4.7 x 4.5 x 4.1 cm.
3. Tumor quantitation: Tumor present in distal right posterior segment only, less than 5% of volume.
4. Gleason grade:
- a. Primary pattern: 3/5.
- b. Secondary pattern: 4/5.
- c. Total Gleason score: 7/10.
5. Extraprostatic extension: Not identified.
6. Seminal vesicle involvement: Not identified.
7. Lymphovascular space invasion: Not identified.
8. High grade PIN: Not identified.
9. Treatment effect: Not identified.

Surgical Margin Status:

1. Margins uninvolved: Inked surface margins uninvolved by tumor.

2. Margins involved: None.

Lymph Node Status: See part B

Other:

1. Other significant findings: Background benign prostatic hyperplasia.

2. pTNM stage: pT2aN0.

B. Bilateral pelvic lymph nodes, excision:

Two lymph nodes, negative for metastatic disease (0/2).

COMMENTS:

CLINICAL HISTORY:

Preoperative Diagnosis: [REDACTED] with prostate cancer, [REDACTED]

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Prostate, bilateral SV, VD

B. Bilateral pelvic lymph nodes

[page 2 of 2]
PROCEDURAL DEMOGRAPHICS:

Date of Procedure: [REDACTED]

Accession Date/Time: [REDACTED]

GROSS DESCRIPTION:

Container A, labeled [REDACTED] and "prostate, SV, VD" is a 39 gm radical prostatectomy specimen previously inked and sampled for research, 4.7 x 4.5 x 4.1 cm. The right side is inked green, the left side black. The specimen is further sectioned to posterior to show a 0.6 cm, pink area of discoloration in the right posterior aspect of the distal to mid level, 0.1 cm from the inked margin. Additional abnormalities are not identified. The seminal vesicles together measure 4.5 x 3.5 x 0.7 cm. Each is uninvolved by lesion. Representative sections are submitted as follows: 1-2 apical margin; 3 vesicle margin; 4 distal left lateral; 5 distal right lateral; 6 distal right posterior; 7 distal left posterior; 8 mid left lateral; 9 mid right lateral; 10 right posterior; 11 left posterior; 12 proximal left lateral; 13 proximal right lateral; 14 proximal right posterior; 15 proximal left posterior; 16 origin of seminal vesicle; 17 representative left and right seminal vesicles; 18-17. Two cassettes for research

labeled [REDACTED]

Container B, labeled [REDACTED] and "bilateral pelvic LN" is a 4.5 x 3.8 x 0.9 cm mass of nodular yellow adipose tissue. On section and palpation two lymph nodes are identified, 2.5 x 1.5 x 0.6 cm and 4.5 x 1.8 x 0.5 cm. Each is sectioned. The nodes are entirely submitted as follows: 1-2 one node bisected; 3-6 one node sectioned;

Source: NCI Genomic Data Commons file 1a36e74b-a28a-45b5-b169-b1e9b8fec952 (TCGA-HC-7080.F2BF590A-9473-47FE-89A9-69C480B6C42B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).